Somatic mutation profile of tumor specimen TCGA-B0-5121-01A (aliquot TCGA-B0-5121-01A-02D-1421-08) from TCGA case TCGA-B0-5121, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.5 years (20,635 days).
Specimen TCGA-B0-5121-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 382c1a64-d7a2-41bc-aca6-e8366d532803.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5121-11A (Solid Tissue Normal), aliquot TCGA-B0-5121-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a86b375-23dc-4feb-935c-637b20a90207

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 30, Silent 14, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.1894A>G p.I632V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs1270959979, COSV60630300; called by muse, mutect2, varscan2
- ABCC4 | c.1685T>G p.L562R | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV65317600; called by muse, mutect2, varscan2
- ACSL6 | c.2041C>A p.L681M (on ENST00000379240; = p.L706M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as rs1357744363, COSV57304323; called by muse, mutect2, varscan2
- ADAMTS18 | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51422120; called by muse, mutect2, varscan2
- CARD9 | c.1147A>C p.K383Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59998799; called by muse, mutect2
- CHD4 | c.4664A>C p.E1555A (on ENST00000357008 / NM_001363606.2; = p.E1568A on NM_001273.5) | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.055); catalogued as COSV58909363, COSV58911158; called by muse, mutect2, varscan2
- CNTRL | c.4328C>A p.A1443E | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV53050920, COSV53052635; called by muse, mutect2, varscan2
- COL28A1 | c.3346A>C p.K1116Q | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV68084202; called by muse, mutect2, varscan2
- ELP1 | c.3754G>A p.G1252R | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1234851458, COSV65899593, COSV65900432; called by muse, mutect2, varscan2
- GMPPB | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57539962; called by muse, mutect2, varscan2
- GPR171 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV56386699; called by muse, mutect2, varscan2
- IGF2BP3 | c.207A>T p.E69D | Missense Mutation (SNP) | VAF 119/456 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV51692112; called by muse, mutect2, varscan2
- JMJD6 | c.711T>A p.N237K | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57975419; called by muse, mutect2, varscan2
- L3HYPDH | c.776A>C p.N259T | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as rs1294452117, COSV55967745; called by muse, mutect2, varscan2
- LRRC66 | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV58636452; called by muse, mutect2, varscan2
- MYT1L | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs370776058; called by muse, mutect2, varscan2
- OR9G4 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 110/288 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57249691; called by muse, mutect2, varscan2
- PABPC3 | c.328A>C p.I110L | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55805802; called by muse, mutect2, varscan2
- PDGFRA | c.3090G>T p.E1030D | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57272995; called by muse, mutect2, varscan2
- PDGFRA | c.3091G>T p.E1031* | Nonsense Mutation (SNP) | VAF 39/149 reads (26%) | catalogued as COSV57269813, COSV57271927; called by muse, mutect2, varscan2
- PDS5B | c.1325A>C p.H442P | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59733412; called by muse, mutect2, varscan2
- PHLDB1 | c.1028C>G p.A343G | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as COSV61881522; called by muse, mutect2, varscan2
- SETD2 | c.3339T>G p.Y1113* | Nonsense Mutation (SNP) | VAF 76/206 reads (37%) | catalogued as COSV57448942; called by muse, mutect2, varscan2
- SLC41A1 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.165); catalogued as COSV65651387; called by muse, mutect2, varscan2
- SPATA22 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs371455241; called by muse, mutect2, varscan2
- SZT2 | c.9944C>A p.S3315Y (on ENST00000634258 / NM_001365999.1; = p.S3258Y on NM_015284.4) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV65095291; called by muse, mutect2
- TPR | c.2470-1G>C p.X824_splice | Splice Site (SNP) | VAF 8/212 reads (4%) | catalogued as COSV66604362; called by muse, mutect2
- TPTE2 | c.785G>T p.R262L (on ENST00000400230 / NM_199254.2; = p.R185L on NM_130785.3) | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV55023284, COSV55027017; called by muse, mutect2, varscan2
- TRMT1L | c.935C>G p.S312C | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as COSV62273244; called by muse, mutect2, varscan2
- TSPYL6 | c.867G>T p.R289S | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV57819392; called by muse, mutect2, varscan2
- TTBK1 | c.1588G>T p.V530L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV52495804; called by muse, mutect2, varscan2
- ZNF184 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV53004936; called by muse, mutect2, varscan2
- ZZEF1 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs1176007046, COSV67559867; called by muse, mutect2, varscan2
- GPR89B | c.287del p.Y96Ffs*4 | Frame Shift Del (DEL) | VAF 109/608 reads (18%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1248dup p.Y417Ifs*3 | Frame Shift Ins (INS) | VAF 83/254 reads (33%) | called by mutect2, pindel, varscan2
- RPAP1 | c.389del p.P130Lfs*32 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- ZNF692 | c.476-3_481del p.X159_splice | Splice Site (DEL) | VAF 43/177 reads (24%) | called by mutect2, pindel, varscan2
- AHNAK | c.4614C>T p.D1538= | Silent (SNP) | VAF 133/414 reads (32%) | catalogued as rs1372183827, COSV57227579; called by muse, mutect2, varscan2
- BAIAP3 | c.423G>A p.E141= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV60983428; called by muse, mutect2, varscan2
- BEST3 | c.468C>T p.H156= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs370248128; called by muse, mutect2
- DGCR2 | c.165G>T p.A55= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV54219977; called by muse, mutect2, varscan2
- DSC1 | c.1269C>T p.N423= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV57150687; called by muse, mutect2
- KATNIP | c.1719T>C p.V573= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV55190308; called by muse, mutect2, varscan2
- NUP205 | c.1809C>A p.L603= | Silent (SNP) | VAF 47/168 reads (28%) | catalogued as COSV53665077; called by muse, mutect2, varscan2
- OR4D9 | c.72C>T p.S24= | Silent (SNP) | VAF 94/336 reads (28%) | catalogued as COSV61435422; called by muse, mutect2, varscan2
- PATJ | c.4293C>T p.V1431= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as COSV56252639; called by muse, mutect2, varscan2
- PCGF1 | c.744G>A p.L248= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV52044331; called by muse, mutect2, varscan2
- SLC3A2 | c.1143C>T p.N381= | Silent (SNP) | VAF 56/222 reads (25%) | catalogued as COSV58604658; called by muse, mutect2, varscan2
- TAAR6 | c.828T>A p.I276= | Silent (SNP) | VAF 79/260 reads (30%) | catalogued as COSV51584756; called by muse, mutect2, varscan2
- TMTC2 | c.2445A>G p.T815= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV58281834; called by muse, mutect2, varscan2
- WDR72 | c.114G>A p.E38= | Silent (SNP) | VAF 77/277 reads (28%) | catalogued as rs1470866961, COSV64752852; called by muse, mutect2, varscan2
